Gene-level copy-number profile of tumor specimen TCGA-06-0744-01A from TCGA case TCGA-06-0744, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.0 years (24,471 days).
Specimen TCGA-06-0744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.5fa7db3a-3f55-4a9a-be6e-107849d34fbd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0744-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a7cfb01-a1b5-4de8-8d7b-87b0b3895fc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 7,452; copy number 2: 43,898; copy number 3: 8,093; copy number 4: 301; copy number 17: 3; copy number 18: 3; copy number 19: 5; copy number 34: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0744-01A-01D-0333-01): tumor purity 0.89, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:18,858,906–19,049,358, 1 gene (within-gene range 0–1): SAXO1.
- chr9:21,058,771–22,128,103, 53 genes: IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,752,250–55,211,628, 5 genes, copy number 34: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr9:77,423,079–77,648,322, 1 gene, copy number 18 (within-gene range 2–18): GNA14.
- chr9:77,580,245–77,635,309, 2 genes, copy number 18: NUTF2P3, RNU6-1303P.
- chr9:99,906,654–99,974,534, 1 gene, copy number 17 (within-gene range 1–17): STX17.
- chr9:99,979,185–100,099,000, 2 genes, copy number 17 (within-gene range 1–17): ERP44, UPF3AP3.
- chr9:100,912,320–100,912,741, 1 gene, copy number 19: AL162395.1.
- chr9:101,387,633–101,449,933, 4 genes, copy number 19 (within-gene range 1–19): MRPL50, ZNF189, ALDOB, AL353621.2.

Autosomal genes at a single copy (total copy number 1): 5,065. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
